Somatic mutation profile of tumor specimen 0DQB2W from CCDI case PBCEVI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,456 days).
Specimen 0DQB2W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e4ac42b-d1c8-405e-929f-6c808451b365.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQB25 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8660580-231e-4619-a399-51088963f149

The open-access MAF lists 10,883 somatic variants for this specimen: 6,592 protein-altering or splice-affecting, 2,543 silent, 1,748 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,821, Silent 2,543, Intron 994, 3'UTR 427, Nonsense Mutation 386, 5'UTR 201, Splice Region 148, Frame Shift Ins 124, Splice Site 100, 5'Flank 49, RNA 41, 3'Flank 36.

Variants (750 of 10,883; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 178/396 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs137852871, CM950135; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAD9 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 134/351 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753711253, COSV100458917; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 208/400 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1057523568, COSV61391392; ClinVar: likely pathogenic; called by muse, varscan2
- ATM | c.8545C>T p.R2849* | Nonsense Mutation (SNP) | VAF 272/593 reads (46%) | catalogued as rs587778080, CM990221, COSV53771567; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.2905C>T p.R969W | Missense Mutation (SNP) | VAF 266/583 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774028495, CM076003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BLM | c.2875C>T p.R959* | Nonsense Mutation (SNP) | VAF 170/352 reads (48%) | catalogued as rs762354041, COSV61922766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 40/491 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs371174955; ClinVar: likely pathogenic; called by muse, mutect2
- CAPN3 | c.717dup p.E240* | Frame Shift Ins (INS) | VAF 278/593 reads (47%) | catalogued as rs776059672; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CHD7 | c.6148C>T p.R2050* | Nonsense Mutation (SNP) | VAF 210/524 reads (40%) | catalogued as rs886040996, CM060915; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.2434C>T p.R812W (on ENST00000646647 / NM_001170629.2; = p.R533W on NM_020920.4) | Missense Mutation (SNP) | VAF 172/466 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518651, COSV67872050; ClinVar: likely pathogenic; called by muse, varscan2
- COL3A1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 282/676 reads (42%) | catalogued as rs1333421028, COSV100482209; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1592C>T p.T531M (on ENST00000399959; = p.T532M on NM_001356.5) | Missense Mutation (SNP) | VAF 24/633 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795387, COSV67863875; ClinVar: pathogenic; called by muse, mutect2
- DEPDC5 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 146/322 reads (45%) | catalogued as rs886039255, CM164373, COSV99835332; ClinVar: pathogenic; called by muse, varscan2
- DEPDC5 | c.2386C>T p.R796* (on ENST00000400246; = p.R865* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 160/313 reads (51%) | catalogued as rs578185749, CM146221, COSV99835340; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHODH | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs267606768, CM100134, COSV54662605; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC2H1 | c.11049G>A p.P3683= | Silent (SNP) | VAF 185/386 reads (48%) | catalogued as rs764926983; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ECEL1 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 193/423 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs606231471, CM1410209; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FANCI | c.3853C>T p.R1285* (on ENST00000310775 / NM_001376911.1; = p.R1225* on NM_018193.3) | Nonsense Mutation (SNP) | VAF 239/549 reads (44%) | catalogued as rs121918164, CM074782, CM125195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXL4 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 154/375 reads (41%) | catalogued as rs964532159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 268/614 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs121909673, CM011783; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GALT | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 212/479 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111033802, CM990673, COSV100535360; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GAMT | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 130/240 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374724533, CM099575; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GATA1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 165/292 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907207, CM070935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GCDH | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 138/299 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.733); catalogued as rs748275416, CM980875, COSV53368773; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 157/351 reads (45%) | catalogued as rs72555372, CM003857; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GPI | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 132/282 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs137853585, CM960785; ClinVar: pathogenic; called by muse, varscan2
- HEXA | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 187/463 reads (40%) | catalogued as rs121907963, CM910218, COSV51506822; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HGSNAT | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 104/275 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766835582, CM065258, COSV52817500, COSV99034812; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- INPPL1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 148/360 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53353022, COSV99995692; called by muse, mutect2, varscan2
- JAG1 | c.1205dup p.Q403Tfs*13 | Frame Shift Ins (INS) | VAF 230/514 reads (45%) | catalogued as rs35615084; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 199/426 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199472763, CM043852, CM970828; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.2352T>G p.Y784* | Nonsense Mutation (SNP) | VAF 282/568 reads (50%) | catalogued as rs886044330, COSV101370957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LZTFL1 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 96/380 reads (25%) | catalogued as rs769327864, COSV56111379; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 225/573 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs28935468, CM993354, COSV100318414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 40/533 reads (8%) | catalogued as rs63750019, CM085563, COSV52275939; ClinVar: pathogenic; called by muse, mutect2
- MYH7 | c.4135G>A p.A1379T | Missense Mutation (SNP) | VAF 277/627 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs397516202, CM020288; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs387906700, CM103009; ClinVar: pathogenic; called by muse, mutect2
- MYPN | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 176/395 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205457, COSV62733066; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NBEA | c.6637C>T p.R2213* | Nonsense Mutation (SNP) | VAF 229/535 reads (43%) | catalogued as rs878853169, COSV59803600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1738dup p.Y580Lfs*8 | Frame Shift Ins (INS) | VAF 184/426 reads (43%) | catalogued as rs786204255; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.5305C>T p.R1769* (on ENST00000358273 / NM_001042492.3; = p.R1748* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 128/317 reads (40%) | catalogued as rs876657714, CM941094, COSV62196320; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 158/365 reads (43%) | catalogued as rs146140738, COSV54984601; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAX2 | c.76dup p.V26Gfs*28 | Frame Shift Ins (INS) | VAF 180/428 reads (42%) | catalogued as rs75462234; ClinVar: pathogenic; called by mutect2, varscan2
- PDGFRA | c.1977C>A p.N659K | Missense Mutation (SNP) | VAF 224/741 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519700, COSV57264866, COSV57265972; ClinVar: pathogenic; called by mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 262/531 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 46/664 reads (7%) | catalogued as rs772468452, COSV54749843, COSV99529486; ClinVar: pathogenic; called by muse, mutect2
- RINT1 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 116/305 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs545894353; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPH3 | c.1105C>T p.R369* (on ENST00000252655; = p.R227* on NM_031924.8) | Nonsense Mutation (SNP) | VAF 114/273 reads (42%) | catalogued as rs796052119, CM157018, COSV51922894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.4976C>T p.A1659V | Missense Mutation (SNP) | VAF 44/1005 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060503101, COSV51839926; ClinVar: pathogenic; called by muse, mutect2
- SPAST | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs878854990, CM042786, CM101457, COSV59518285; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 195/424 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTBK1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 138/334 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs759748655; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTC7A | c.2515G>A p.A839T | Missense Mutation (SNP) | VAF 191/424 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202044972; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.99490C>T p.R33164* (on ENST00000591111; = p.R25740* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 212/586 reads (36%) | catalogued as rs750519430, COSV60279899; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.64630C>T p.R21544* (on ENST00000591111; = p.R14120* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 84/970 reads (9%) | catalogued as rs878854328, COSV60187591; ClinVar: likely pathogenic; called by muse, mutect2
- TTN | c.3034C>T p.R1012* (on ENST00000591111; = p.R966* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 296/728 reads (41%) | catalogued as rs397517547, CM1410919, COSV59870865; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WDR72 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 243/589 reads (41%) | catalogued as rs557128345, CM109077, COSV64751129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 353/779 reads (45%) | catalogued as rs587784571, CM041103, COSV100355710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1688C>T p.A563V (on ENST00000373993 / NM_138932.2; = p.A555V on NM_014576.4) | Missense Mutation (SNP) | VAF 68/760 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1433268857; called by muse, mutect2
- AATK | c.2765C>T p.P922L (on ENST00000326724 / NM_001080395.3; = p.P819L on NM_004920.2) | Missense Mutation (SNP) | VAF 213/492 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as rs771746107; called by muse, varscan2
- AATK | c.2113G>A p.A705T (on ENST00000326724 / NM_001080395.3; = p.A602T on NM_004920.2) | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1449450790; called by muse, mutect2, varscan2
- ABCA12 | c.2957G>A p.R986Q (on ENST00000272895 / NM_173076.3; = p.R668Q on NM_015657.3) | Missense Mutation (SNP) | VAF 72/716 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs116481578; called by muse, mutect2, varscan2
- ABCA13 | c.6620A>C p.N2207T | Missense Mutation (SNP) | VAF 396/858 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV101330125; called by muse, mutect2, varscan2
- ABCA13 | c.14186G>A p.R4729H | Missense Mutation (SNP) | VAF 270/602 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs372286953, COSV68943281; called by muse, mutect2, varscan2
- ABCA2 | c.4783C>T p.R1595C (on ENST00000614293; = p.R1565C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs772250768, COSV55798148; called by muse, mutect2, varscan2
- ABCA2 | c.4283G>A p.R1428H (on ENST00000614293; = p.R1398H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/542 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs761540588, COSV55806537; called by muse, mutect2, varscan2
- ABCA2 | c.3007C>T p.R1003C (on ENST00000614293; = p.R973C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 243/531 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs768820688, COSV55798187; called by muse, mutect2, varscan2
- ABCA3 | c.4028G>A p.R1343Q | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs201643902, COSV57061684; called by muse, varscan2
- ABCA6 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 223/465 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.217); catalogued as rs756546789, COSV104371215; called by muse, mutect2, varscan2
- ABCA7 | c.4060C>T p.R1354C | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as rs776084636; called by muse, mutect2, varscan2
- ABCB10 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 180/426 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs149933923; called by muse, mutect2, varscan2
- ABCB6 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 190/452 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.906); catalogued as rs995316648; called by muse, mutect2, varscan2
- ABCB9 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs139273443; called by muse, mutect2, varscan2
- ABCC10 | c.3019C>T p.R1007* (on ENST00000372530 / NM_001198934.2; = p.R979* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 170/372 reads (46%) | catalogued as rs748423333; called by muse, mutect2, varscan2
- ABCC10 | c.4400G>A p.R1467H (on ENST00000372530 / NM_001198934.2; = p.R1439H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/334 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs762227822, COSV55096107; called by muse, varscan2
- ABCC11 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 141/319 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs150250426; called by muse, mutect2, varscan2
- ABCC11 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200134154; called by muse, mutect2, varscan2
- ABCC12 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 224/559 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs1429335721; called by muse, mutect2, varscan2
- ABCC2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 179/416 reads (43%) | catalogued as rs529588584, CM035497, COSV64970800; called by muse, mutect2, varscan2
- ABCC8 | c.3022G>A p.G1008S | Missense Mutation (SNP) | VAF 178/379 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs759164351; called by muse, mutect2, varscan2
- ABCF1 | c.1492C>T p.R498W (on ENST00000326195 / NM_001025091.2; = p.R460W on NM_001090.3) | Missense Mutation (SNP) | VAF 143/325 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58231256; called by muse, mutect2, varscan2
- ABCF2 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 245/512 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs569105816, COSV99033370; called by muse, mutect2, varscan2
- ABCF3 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 47/481 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs760328153, COSV53049556; called by muse, mutect2
- ABCG1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1362774007, COSV100494409; called by muse, mutect2
- ABHD14B | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 253/553 reads (46%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs746826851; called by muse, mutect2, varscan2
- ABHD16A | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149790845; called by muse, mutect2, varscan2
- ABHD17C | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 168/349 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99358899; called by muse, mutect2, varscan2
- ABL1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs368646202; called by muse, mutect2, varscan2
- ABL1 | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 24/415 reads (6%) | catalogued as COSV59336112; called by muse, mutect2
- ABRA | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100357689; called by muse, mutect2
- AC004593.2 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 49/475 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs758969689; called by muse, mutect2, varscan2
- AC006059.2 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 188/449 reads (42%) | catalogued as rs564647857, COSV100045189; called by muse, mutect2, varscan2
- AC011455.2 | c.1626C>T p.D542= | Splice Region (SNP) | VAF 107/264 reads (41%) | catalogued as rs151125003; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC013489.1 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 199/391 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51552426; called by muse, mutect2, varscan2
- AC013489.1 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 135/303 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs34532160; called by muse, mutect2, varscan2
- AC020907.6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 150/330 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767430965, COSV59533471, COSV59534647; called by muse, mutect2, varscan2
- AC068580.4 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 153/372 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs367743333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC092143.1 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 168/319 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1367183465; called by muse, mutect2, varscan2
- AC109583.1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1391916141; called by muse, mutect2
- AC109583.1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 164/336 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs768769548, COSV59350985; called by muse, mutect2, varscan2
- AC132217.2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 242/494 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as rs1384290487; called by muse, mutect2, varscan2
- ACACA | c.4603C>T p.R1535W | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1019398644; called by muse, mutect2, varscan2
- ACACB | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 115/234 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.531); catalogued as rs202035669, COSV58149256; called by muse, mutect2, varscan2
- ACAD10 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 160/396 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs887353946; called by muse, mutect2, varscan2
- ACADL | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs372200569; called by muse, mutect2
- ACADS | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 162/369 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766183395, CM164828; called by muse, mutect2, varscan2
- ACAP1 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 108/225 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50139755; called by muse, mutect2, varscan2
- ACAP3 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 196/457 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs139733875; called by muse, mutect2, varscan2
- ACBD3 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 123/318 reads (39%) | catalogued as rs777244895, COSV100830973; called by muse, mutect2, varscan2
- ACE | c.3802G>A p.A1268T | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs757997489; called by muse, mutect2, varscan2
- ACIN1 | c.3787C>T p.R1263W | Missense Mutation (SNP) | VAF 237/521 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.985); catalogued as rs761014319; called by muse, varscan2
- ACIN1 | c.3554G>A p.R1185H | Missense Mutation (SNP) | VAF 181/456 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs371108687; called by muse, mutect2, varscan2
- ACIN1 | c.1673G>A p.R558K | Missense Mutation (SNP) | VAF 222/504 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1301290312, COSV52980360; called by muse, mutect2, varscan2
- ACLY | c.3216C>A p.H1072Q | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59863014; called by muse, mutect2
- ACLY | c.1341G>A p.T447= | Splice Region (SNP) | VAF 88/239 reads (37%) | catalogued as rs1555630716, COSV100709653; called by muse, mutect2, varscan2
- ACLY | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs782746157, COSV61251431; called by muse, mutect2, varscan2
- ACLY | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.98); catalogued as rs1555633148, COSV61249908; called by muse, mutect2, varscan2
- ACOT11 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1238728610; called by muse, mutect2, varscan2
- ACOT7 | c.1109C>T p.A370V (on ENST00000377855 / NM_181864.3; = p.A360V on NM_007274.4) | Missense Mutation (SNP) | VAF 147/394 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs578211150, COSV100830266; called by muse, mutect2, varscan2
- ACR | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 232/502 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as rs764777015, COSV53361724; called by muse, mutect2, varscan2
- ACSF3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 121/241 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs745633046, COSV58081288; called by muse, mutect2, varscan2
- ACSM1 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 154/288 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs563014407; called by muse, mutect2, varscan2
- ACSM2B | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 237/539 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV100313085; called by muse, mutect2, varscan2
- ACSS2 | c.806dup p.I270Nfs*2 | Frame Shift Ins (INS) | VAF 100/222 reads (45%) | catalogued as rs745681981; called by mutect2, varscan2
- ACTL6B | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs780636767, COSV50518996; called by muse, mutect2, varscan2
- ACTN1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 250/554 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.117); catalogued as rs201419872, COSV51994635; called by muse, mutect2, varscan2
- ACTN1 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 264/625 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as rs747350137, CM154192; called by muse, mutect2
- ACTN2 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 176/426 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs142142718; ClinVar: uncertain significance; called by muse, mutect2
- ACTN2 | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.278); catalogued as rs769239899; called by muse, mutect2, varscan2
- ACTRT1 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 181/459 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV64419932; called by muse, mutect2, varscan2
- ADAM15 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 161/396 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as rs1234492492; called by muse, mutect2, varscan2
- ADAM17 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 154/317 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as COSV60397756; called by muse, mutect2, varscan2
- ADAM18 | c.196T>A p.L66I | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); catalogued as COSV55850845; called by muse, mutect2, varscan2
- ADAM19 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 125/318 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs759459737; called by muse, mutect2, varscan2
- ADAM29 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 249/578 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs757836207; called by muse, mutect2, varscan2
- ADAM33 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 200/432 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs779317899, COSV62933451; called by muse, mutect2, varscan2
- ADAM8 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 220/480 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs567552156; called by muse, mutect2, varscan2
- ADAMTS16 | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 230/534 reads (43%) | catalogued as COSV99942260; called by muse, mutect2, varscan2
- ADAMTS17 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs756721876, COSV99171736; called by muse, mutect2, varscan2
- ADAMTS19 | c.2039G>A p.R680K | Missense Mutation (SNP) | VAF 191/431 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs766748428; called by muse, mutect2, varscan2
- ADAMTS20 | c.3295C>T p.R1099* | Nonsense Mutation (SNP) | VAF 212/511 reads (41%) | catalogued as rs757261794, COSV101166089; called by muse, mutect2, varscan2
- ADAMTS20 | c.1523A>G p.H508R | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771801794; called by muse, mutect2, varscan2
- ADAMTS3 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 272/570 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.208); catalogued as rs150114537; called by muse, mutect2, varscan2
- ADAMTS4 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 159/356 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206776400, COSV63490631; called by muse, mutect2, varscan2
- ADAMTS4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1243925734, COSV63487580; called by muse, mutect2
- ADAMTS6 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 224/510 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.327); catalogued as COSV66862422; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 253/583 reads (43%) | catalogued as rs761956033, COSV52815302; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 120/240 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs3004643, COSV65889692; called by muse, varscan2
- ADAMTSL1 | c.4027G>A p.V1343M | Missense Mutation (SNP) | VAF 223/560 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs374073733; called by muse, mutect2, varscan2
- ADAMTSL2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 141/362 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242674081, COSV63204290; called by muse, mutect2, varscan2
- ADAT3 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1344431041; called by muse, mutect2, varscan2
- ADCK2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 214/468 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs376548364; called by muse, mutect2, varscan2
- ADCK5 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782000623; called by muse, mutect2, varscan2
- ADCK5 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 25/641 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1021197375; called by muse, mutect2
- ADCY1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 225/510 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1228715407, COSV52038929; called by muse, mutect2, varscan2
- ADCY3 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 268/550 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.415); catalogued as COSV53167664; called by muse, varscan2
- ADCY3 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 202/438 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1241420296, COSV53169554; called by muse, varscan2
- ADCY3 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430218908, COSV99568889; called by muse, mutect2, varscan2
- ADCY4 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 54/115 reads (47%) | catalogued as rs140912494; called by muse, mutect2, varscan2
- ADCY4 | c.819C>T p.S273= | Splice Region (SNP) | VAF 139/293 reads (47%) | catalogued as rs376471269; called by muse, mutect2, varscan2
- ADCY7 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 208/416 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs750457491, COSV54265110; called by muse, mutect2, varscan2
- ADCY7 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 47/501 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139215312; called by muse, mutect2
- ADD2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 142/368 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs782644174, COSV52455124; called by muse, mutect2, varscan2
- ADGB | c.4771C>T p.R1591W | Missense Mutation (SNP) | VAF 257/540 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1248791153; called by muse, mutect2, varscan2
- ADGRA1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 158/311 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.233); catalogued as rs960359661, COSV66924818; called by muse, mutect2, varscan2
- ADGRA1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 291/596 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.166); catalogued as rs761682447; called by muse, mutect2
- ADGRA1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 143/335 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs761180491, COSV66925940; called by muse, mutect2, varscan2
- ADGRB1 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 173/349 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781191668, COSV60097393; called by muse, mutect2, varscan2
- ADGRB2 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 256/542 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs772354080; called by muse, varscan2
- ADGRB2 | c.2837C>T p.A946V | Missense Mutation (SNP) | VAF 314/670 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs762450749; called by muse, varscan2
- ADGRB2 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 200/500 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs747623212, COSV57079068; called by muse, mutect2, varscan2
- ADGRF5 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 149/357 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs199576297, COSV51930052; called by muse, mutect2, varscan2
- ADGRG5 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 164/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs201549132, COSV61083297; called by muse, mutect2, varscan2
- ADGRG5 | c.1512C>A p.C504* | Nonsense Mutation (SNP) | VAF 166/338 reads (49%) | catalogued as COSV100446347; called by muse, mutect2, varscan2
- ADGRL2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 173/373 reads (46%) | catalogued as COSV54650641; called by muse, mutect2, varscan2
- ADGRL2 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 259/588 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV54649412; called by muse, mutect2, varscan2
- ADGRL4 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 269/652 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as rs376274683, COSV66063260; called by muse, mutect2, varscan2
- ADHFE1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 191/418 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772246039; called by muse, mutect2, varscan2
- ADORA1 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58809000; called by muse, mutect2, varscan2
- ADPGK | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 172/398 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968556047, COSV100295137; called by muse, mutect2, varscan2
- ADRA2B | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 180/354 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787924; called by muse, mutect2, varscan2
- AEBP1 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 234/468 reads (50%) | catalogued as rs1396903800, COSV56255171, COSV99788992; called by muse, mutect2, varscan2
- AEBP1 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 196/422 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56257432; called by muse, varscan2
- AEBP2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as rs1468971286; called by muse, varscan2
- AFAP1L1 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 220/463 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759195126; called by muse, mutect2, varscan2
- AFDN | c.4900C>T p.R1634C (on ENST00000447894 / NM_001366320.1; = p.R1632C on NM_001040000.3) | Missense Mutation (SNP) | VAF 270/607 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as rs781720897, COSV60053577; called by muse, mutect2, varscan2
- AFF4 | c.2552C>T p.T851M | Missense Mutation (SNP) | VAF 187/450 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as rs769422062, COSV54793685; called by muse, mutect2, varscan2
- AGAP1 | c.1726C>T p.R576W (on ENST00000304032 / NM_001037131.3; = p.R523W on NM_014914.5) | Missense Mutation (SNP) | VAF 162/365 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58326271; called by muse, mutect2, varscan2
- AGAP2 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 208/444 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs963412547; called by muse, mutect2, varscan2
- AGAP3 | c.557G>A p.R186H (on ENST00000622464; = p.R222H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 295/666 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs746194907, COSV58994376; called by muse, mutect2, varscan2
- AGAP4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1327009720, COSV71164763; called by muse, mutect2, varscan2
- AGBL1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 224/505 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.02); catalogued as COSV69811190; called by muse, mutect2, varscan2
- AGBL2 | c.189dup p.D64Rfs*2 | Frame Shift Ins (INS) | VAF 150/342 reads (44%) | catalogued as rs535614031; called by mutect2, varscan2
- AGO1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 153/349 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs1262161642, COSV64595240, COSV64596117; called by muse, mutect2, varscan2
- AGPAT1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 230/519 reads (44%) | catalogued as COSV61246915, COSV61248990; called by muse, mutect2, varscan2
- AGPAT5 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 202/515 reads (39%) | catalogued as rs752941173, COSV53446129; called by muse, mutect2, varscan2
- AGRN | c.3604G>A p.A1202T | Missense Mutation (SNP) | VAF 228/457 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs148948883, COSV101039201; called by muse, mutect2, varscan2
- AGRN | c.3715C>T p.R1239W | Missense Mutation (SNP) | VAF 183/449 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs571142975, COSV65069829; called by muse, mutect2, varscan2
- AHCTF1 | c.3500C>T p.S1167L (on ENST00000366508; = p.S1141L on NM_015446.5) | Missense Mutation (SNP) | VAF 206/455 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs562355764; called by muse, mutect2, varscan2
- AHDC1 | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs371087154, COSV55939540; called by muse, varscan2
- AHDC1 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 120/221 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs761521190; called by muse, mutect2, varscan2
- AHNAK | c.13471C>T p.P4491S | Missense Mutation (SNP) | VAF 222/498 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1256596124; called by muse, mutect2, varscan2
- AIFM2 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 213/420 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV57158540; called by muse, mutect2, varscan2
- AIRE | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 139/308 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs554954634, COSV52393789; called by muse, mutect2, varscan2
- AK1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 187/390 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs150701679; called by muse, mutect2, varscan2
- AKAP11 | c.5032G>A p.G1678R | Missense Mutation (SNP) | VAF 293/653 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747035955; called by muse, mutect2, varscan2
- AKAP12 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 154/345 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs769926929, COSV53570776; called by muse, mutect2, varscan2
- AKAP13 | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 146/283 reads (52%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs776205323; called by muse, mutect2, varscan2
- AKAP17A | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 275/554 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); catalogued as rs150761689; called by muse, mutect2, varscan2
- AKAP17A | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 232/455 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); catalogued as COSV100002020; called by muse, mutect2, varscan2
- AKAP3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 178/405 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs140648530; called by muse, varscan2
- AKAP7 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 277/545 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.216); catalogued as COSV53836229; called by muse, mutect2, varscan2
- AKNAD1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 60/729 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs147307662; called by muse, mutect2
- AKR1C3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 211/949 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs1305543060; called by muse, varscan2
- AKR1E2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 154/362 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1438852883, COSV53630416; called by muse, mutect2, varscan2
- AKR7L | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 156/343 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as rs1305890048; called by muse, mutect2, varscan2
- AKT1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 220/470 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs756697784; called by muse, mutect2
- AL035461.3 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 201/462 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); catalogued as rs371425827; called by muse, mutect2, varscan2
- AL136295.1 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 115/290 reads (40%) | catalogued as rs866796538; called by muse, mutect2, varscan2
- ALDH1A3 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 152/357 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs371736673; called by muse, mutect2, varscan2
- ALDH1B1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs61757680; called by muse, mutect2, varscan2
- ALDH4A1 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 30/430 reads (7%) | catalogued as COSV99311983; called by muse, mutect2
- ALDH9A1 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 205/439 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321371155; called by muse, mutect2, varscan2
- ALG1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs748038529; called by muse, varscan2
- ALG12 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 115/233 reads (49%) | PolyPhen benign (0.001); catalogued as rs371860013; called by muse, mutect2, varscan2
- ALG1L | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 212/469 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs774631867; called by muse, varscan2
- ALG2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 217/478 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99445381; called by muse, mutect2, varscan2
- ALG9 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 209/466 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782123768, COSV67644339; called by muse, mutect2, varscan2
- ALK | c.4426G>A p.V1476M | Missense Mutation (SNP) | VAF 194/428 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.499); catalogued as rs1353772576, COSV66557158, COSV66564259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.3944C>T p.A1315V | Missense Mutation (SNP) | VAF 251/557 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs750671777, COSV52510144; called by muse, mutect2, varscan2
- ALOX12B | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV100047070; called by muse, mutect2, varscan2
- ALOX5 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 239/511 reads (47%) | catalogued as COSV65551085, COSV65552066; called by muse, mutect2, varscan2
- ALPG | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 189/503 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs542023570, COSV54964900; called by muse, mutect2, varscan2
- ALPG | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 143/312 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1407092457, COSV99779098; called by muse, mutect2, varscan2
- ALPP | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 211/713 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs766110386, COSV101235110; called by muse, mutect2, varscan2
- ALYREF | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 158/363 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58669151, COSV58669210; called by muse, mutect2, varscan2
- AMER1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 293/587 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs759613339, COSV100367201; called by muse, mutect2, varscan2
- AMOT | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 58/662 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs754951320; called by muse, mutect2
- AMOTL1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 249/554 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759915086, COSV58570823; called by muse, mutect2, varscan2
- AMOTL2 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 210/450 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs545800849, COSV51439035; called by muse, mutect2, varscan2
- AMPD3 | c.505G>A p.A169T (on ENST00000396553 / NM_001025389.2; = p.A178T on NM_000480.3) | Missense Mutation (SNP) | VAF 46/520 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs779211791, COSV67332404; called by muse, mutect2
- AMZ1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.37); catalogued as rs201114825, COSV100406620; called by muse, mutect2
- ANAPC7 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV71444034; called by muse, mutect2
- ANK2 | c.3032G>A p.R1011H | Missense Mutation (SNP) | VAF 38/644 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563808779, COSV52144383; called by muse, mutect2
- ANK2 | c.6247G>T p.G2083* | Nonsense Mutation (SNP) | VAF 296/657 reads (45%) | catalogued as COSV52172252; called by muse, mutect2, varscan2
- ANK2 | c.6874C>T p.R2292* | Nonsense Mutation (SNP) | VAF 364/804 reads (45%) | catalogued as COSV100001468; called by muse, mutect2, varscan2
- ANK2 | c.7508C>T p.A2503V | Missense Mutation (SNP) | VAF 273/525 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.453); catalogued as COSV99999097; called by muse, mutect2, varscan2
- ANK2 | c.10147G>A p.A3383T | Missense Mutation (SNP) | VAF 229/553 reads (41%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs374257100, COSV52188715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV51845307; called by muse, mutect2, varscan2
- ANKIB1 | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 247/513 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as rs766956969; called by muse, mutect2, varscan2
- ANKLE1 | c.1489C>T p.R497W (on ENST00000394458; = p.R443W on NM_152363.6) | Missense Mutation (SNP) | VAF 128/253 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748154981, COSV104421581; called by muse, mutect2, varscan2
- ANKMY1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 100/194 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs769468041, COSV56040967; called by muse, mutect2
- ANKRD1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 227/510 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as COSV65468598; called by muse, varscan2
- ANKRD10 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 128/349 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377282087; called by muse, mutect2, varscan2
- ANKRD12 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50837182; called by muse, varscan2
- ANKRD12 | c.6038C>T p.A2013V | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs958947092, COSV50819165; called by muse, mutect2
- ANKRD17 | c.3794C>T p.T1265I | Missense Mutation (SNP) | VAF 238/515 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.631); catalogued as COSV100428763; called by muse, mutect2, varscan2
- ANKRD18B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 181/519 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1234074751; called by muse, mutect2, varscan2
- ANKRD20A1 | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 148/620 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs28645645; called by muse, varscan2
- ANKRD20A1 | c.1155C>T p.V385= | Splice Region (SNP) | VAF 40/292 reads (14%) | catalogued as rs1417999864; called by muse, mutect2, varscan2
- ANKRD22 | c.281T>A p.I94N | Missense Mutation (SNP) | VAF 210/455 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.347); catalogued as rs376412609; called by muse, mutect2, varscan2
- ANKRD23 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 92/203 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1161135076; called by muse, mutect2, varscan2
- ANKRD26 | c.3734C>T p.T1245M | Missense Mutation (SNP) | VAF 193/422 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs770749364, COSV65774423; called by muse, mutect2, varscan2
- ANKRD27 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 133/278 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs757626430; called by muse, mutect2, varscan2
- ANKRD28 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs973722986; called by muse, mutect2, varscan2
- ANKRD28 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs756948440; called by muse, mutect2
- ANKRD31 | c.4780C>A p.L1594I | Missense Mutation (SNP) | VAF 52/470 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as COSV57159205; called by muse, varscan2
- ANKRD33B | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 149/312 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1358562200; called by muse, mutect2, varscan2
- ANKRD35 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 237/534 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs782190439, COSV62909764; called by muse, mutect2, varscan2
- ANKRD36C | c.4802G>A p.R1601H | Missense Mutation (SNP) | VAF 353/1067 reads (33%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.517); catalogued as rs766400604; called by muse, mutect2, varscan2
- ANKRD39 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 196/409 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs779408031; called by muse, mutect2, varscan2
- ANKS1B | c.2503G>A p.G835R (on ENST00000547776 / NM_152788.4; = p.G61R on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60360868; called by muse, mutect2, varscan2
- ANKZF1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 238/553 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs374716315; called by muse, mutect2, varscan2
- ANLN | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 29/747 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs1387928172; called by muse, mutect2
- ANO1 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 175/364 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as rs937743518; called by muse, mutect2, varscan2
- ANO3 | c.1448C>A p.A483D | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99883882; called by muse, mutect2, varscan2
- ANO7 | c.471+4C>T | Splice Region (SNP) | VAF 37/389 reads (10%) | catalogued as rs769952730, COSV99238615; called by muse, mutect2, varscan2
- ANP32A | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 98/242 reads (40%) | catalogued as COSV51189644; called by muse, mutect2, varscan2
- ANTXRL | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 161/550 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs1439384507; called by muse, mutect2, varscan2
- ANXA11 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 215/473 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756080261; called by muse, mutect2, varscan2
- ANXA3 | c.103+2T>C p.X35_splice | Splice Site (SNP) | VAF 40/347 reads (12%) | catalogued as rs1435622977; called by muse, mutect2, varscan2
- ANXA4 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV67848329; called by muse, mutect2, varscan2
- ANXA4 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 171/396 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761374777, COSV101268796; called by muse, varscan2
- ANXA7 | c.776C>T p.T259M (on ENST00000372919 / NM_001320880.2; = p.T237M on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/271 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.629); catalogued as rs142515398; called by muse, mutect2, varscan2
- AOAH | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 179/430 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs760519168; called by muse, mutect2, varscan2
- AOAH | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 187/424 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV51738418; called by muse, mutect2, varscan2
- AP002748.5 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 160/335 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs759763673, COSV59152593; called by muse, mutect2, varscan2
- AP1B1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 112/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756047868; called by muse, mutect2, varscan2
- AP2A1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as rs774740971; called by muse, mutect2, varscan2
- AP5B1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 31/394 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs547721862; called by muse, mutect2
- APC2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 103/260 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99280024; called by muse, varscan2
- APC2 | c.6550C>T p.R2184C | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1306191793; called by muse, mutect2, varscan2
- APCDD1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs1172288918; called by muse, mutect2
- APEX2 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 43/501 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs767858928, COSV58190349; called by muse, mutect2
- API5 | c.1129C>T p.L377= | Splice Region (SNP) | VAF 46/401 reads (11%) | catalogued as rs777502465; called by muse, mutect2, varscan2
- APLN | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 186/364 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758766922, COSV100278253; called by muse, varscan2
- APLP1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 107/191 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs367756339; called by muse, mutect2, varscan2
- APOB | c.9406C>T p.R3136C | Missense Mutation (SNP) | VAF 307/610 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs72653102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3C | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 211/507 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as rs138675963; called by muse, mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 52/624 reads (8%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2
- APOD | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs764190179; called by muse, mutect2, varscan2
- AQP1 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766229713; called by muse, mutect2, varscan2
- AQP4 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 275/646 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs766479946, COSV67218332; called by muse, mutect2, varscan2
- AQP8 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 136/267 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs777810756, COSV54844511; called by muse, mutect2, varscan2
- ARAF | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.388); catalogued as COSV51694565; called by muse, mutect2
- ARAP1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1393767675, COSV61994758; called by muse, mutect2, varscan2
- ARAP2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 290/673 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749795521, COSV58283421; called by muse, mutect2, varscan2
- ARAP3 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs375039752; called by muse, mutect2, varscan2
- ARAP3 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 148/302 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs766075887, COSV53348263; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 240/571 reads (42%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- AREL1 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 187/410 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs370313422; called by muse, mutect2, varscan2
- ARF1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 116/282 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV55256221; called by muse, mutect2, varscan2
- ARFGAP2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs753762146; called by muse, mutect2, varscan2
- ARFGEF1 | c.4706C>T p.S1569F | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs757127977; called by muse, mutect2, varscan2
- ARFGEF2 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201298117, COSV64212109; called by muse, mutect2, varscan2
- ARFGEF3 | c.5188G>A p.D1730N | Missense Mutation (SNP) | VAF 48/650 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); catalogued as COSV52474346; called by muse, mutect2
- ARG2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 192/371 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1418638295, COSV55777138; called by muse, varscan2
- ARHGAP21 | c.1569dup p.Q524Tfs*10 | Frame Shift Ins (INS) | VAF 215/508 reads (42%) | catalogued as rs1565032132; called by mutect2, varscan2
- ARHGAP22 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372857506; called by muse, varscan2
- ARHGAP22 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 254/518 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.312); catalogued as rs755687175, COSV50932824; called by muse, varscan2
- ARHGAP24 | c.1273G>A p.A425T (on ENST00000395184 / NM_001025616.3; = p.A332T on NM_031305.3) | Missense Mutation (SNP) | VAF 215/448 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs767653652; called by muse, mutect2, varscan2
- ARHGAP24 | c.1715G>A p.R572H (on ENST00000395184 / NM_001025616.3; = p.R479H on NM_031305.3) | Missense Mutation (SNP) | VAF 185/385 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs149024248; called by muse, mutect2, varscan2
- ARHGAP31 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 199/430 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs772471119, COSV51791267; called by muse, mutect2, varscan2
- ARHGAP31 | c.3443C>A p.S1148Y | Missense Mutation (SNP) | VAF 208/428 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV51794734; called by muse, mutect2, varscan2
- ARHGAP32 | c.5278C>T p.R1760C (on ENST00000310343 / NM_001378025.1; = p.R1411C on NM_014715.4) | Missense Mutation (SNP) | VAF 172/399 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149800604; called by muse, mutect2, varscan2
- ARHGAP33 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 51/623 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs757101169; called by muse, mutect2
- ARHGAP33 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs537289034, COSV50156769; called by muse, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 189/413 reads (46%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ARHGAP35 | c.3779C>T p.P1260L | Missense Mutation (SNP) | VAF 166/402 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1568473009, COSV101350677; called by muse, mutect2, varscan2
- ARHGAP39 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 168/304 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV52773253; called by muse, mutect2, varscan2
- ARHGAP39 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 220/480 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs971319980; called by muse, mutect2, varscan2
- ARHGAP4 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 216/528 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs1394791174; called by muse, mutect2, varscan2
- ARHGAP5 | c.4487C>T p.T1496M (on ENST00000345122 / NM_001030055.2; = p.T1495M on NM_001173.3) | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.118); catalogued as rs200147073; called by muse, mutect2, varscan2
- ARHGEF10 | c.217G>A p.A73T (on ENST00000398564; = p.A49T on NM_014629.4) | Missense Mutation (SNP) | VAF 270/606 reads (45%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.028); catalogued as rs559084209, COSV100034071; called by muse, mutect2, varscan2
- ARHGEF10 | c.3245C>T p.A1082V (on ENST00000398564; = p.A1057V on NM_014629.4) | Missense Mutation (SNP) | VAF 230/595 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777115859; called by muse, mutect2, varscan2
- ARHGEF11 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 307/667 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1486825154; called by muse, mutect2, varscan2
- ARHGEF12 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 159/352 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34726241; called by muse, mutect2, varscan2
- ARHGEF17 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 327/630 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.161); catalogued as rs1439459860, COSV55229061, COSV99734802; called by muse, mutect2, varscan2
- ARHGEF17 | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 308/637 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1565206681, COSV55231896; called by muse, mutect2, varscan2
- ARHGEF18 | c.776C>T p.T259M (on ENST00000359920 / NM_001130955.2; = p.T155M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs368462398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF2 | c.2747G>A p.R916H (on ENST00000361247 / NM_001162383.2; = p.R888H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.964); catalogued as rs141465288, COSV58108899; called by muse, mutect2, varscan2
- ARHGEF38 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs749765197, COSV70363895; called by muse, mutect2, varscan2
- ARHGEF5 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 40/731 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV50207938; called by muse, mutect2
- ARHGEF5 | c.4537C>A p.P1513T | Missense Mutation (SNP) | VAF 346/740 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV50210336; called by muse, mutect2, varscan2
- ARHGEF7 | c.1973C>T p.A658V (on ENST00000375741 / NM_001113511.2; = p.A480V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 244/585 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368372361; called by muse, mutect2, varscan2
- ARID2 | c.4675G>A p.G1559R | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV57599379; called by muse, mutect2
- ARID3A | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 29/396 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs1384979178; called by muse, mutect2
- ARID5B | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 99/776 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs756022924; called by muse, mutect2, varscan2
- ARID5B | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 195/446 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as rs145564601, COSV54415348; called by muse, mutect2, varscan2
- ARL13B | c.1025-1G>A p.X342_splice (on ENST00000394222 / NM_001174150.2; = p.X235_splice on NM_144996.4) | Splice Site (SNP) | VAF 90/170 reads (53%) | catalogued as rs1035683333; called by muse, mutect2, varscan2
- ARMC5 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 129/290 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.127); catalogued as rs114040639; called by muse, mutect2, varscan2
- ARMC8 | c.389G>A p.R130H (on ENST00000469044 / NM_001363941.2; = p.R116H on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs896372361, COSV61768635; called by muse, mutect2
- ARMC8 | c.1201C>T p.R401W (on ENST00000469044 / NM_001363941.2; = p.R387W on NM_015396.6) | Missense Mutation (SNP) | VAF 238/541 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1307854914, COSV58620603; called by muse, mutect2, varscan2
- ARMCX2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 28/839 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1556059951, COSV100168006; called by muse, mutect2
- ARMH3 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs758726987, COSV60751327; called by muse, mutect2, varscan2
- ARNTL | c.1333G>A p.V445I (on ENST00000403290 / NM_001297719.2; = p.V444I on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs200152414; called by muse, mutect2, varscan2
- ARPC4 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs751354662; called by muse, mutect2
- ARRDC2 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 159/406 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs372299093; called by muse, mutect2
- ARRDC3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 224/619 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1394065046, COSV54366693; called by muse, mutect2, varscan2
- ARSA | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 200/474 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs1437253036, COSV53350364; called by muse, varscan2
- ARVCF | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 263/579 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54265395; called by muse, mutect2, varscan2
- ASAP2 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 242/462 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766970654, COSV55634692; called by muse, mutect2, varscan2
- ASB1 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 254/535 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs371505177; called by muse, mutect2, varscan2
- ASB10 | c.1367G>A p.R456H (on ENST00000420175 / NM_001142459.2; = p.R441H on NM_080871.4) | Missense Mutation (SNP) | VAF 235/535 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs376633217; called by muse, mutect2, varscan2
- ASB16 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 135/294 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs144140141; called by muse, mutect2, varscan2
- ASCC1 | c.560C>T p.A187V (on ENST00000342444 / NM_001369085.1; = p.A159V on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs778835382; called by muse, varscan2
- ASCL3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 150/308 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs137922914; called by muse, mutect2, varscan2
- ASH1L | c.8866C>T p.R2956* (on ENST00000368346 / NM_001366177.2; = p.R2951* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 48/642 reads (7%) | catalogued as rs776253661, COSV64208132; called by muse, mutect2
- ASH1L | c.5414G>A p.R1805H | Missense Mutation (SNP) | VAF 210/442 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.375); catalogued as rs757302359, COSV100853525, COSV64214797; called by muse, mutect2, varscan2
- ASH1L | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs750694607, COSV64207421; called by muse, mutect2
- ASIC4 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 229/516 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs549589802, COSV61732282; called by muse, mutect2, varscan2
- ASMTL | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 216/538 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1181969621, COSV67243505; called by muse, varscan2
- ASPDH | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1015968343; called by muse, mutect2, varscan2
- ASPHD1 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 174/369 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs538438310, COSV58102850; called by muse, mutect2, varscan2
- ASPM | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 303/675 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs1223154061; called by muse, mutect2, varscan2
- ASTN2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 233/554 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs748550947, COSV100526472, COSV57751743; called by muse, mutect2, varscan2
- ASXL3 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 60/778 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs781769831; called by muse, mutect2
- ASXL3 | c.2797C>T p.R933W | Missense Mutation (SNP) | VAF 334/709 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs376307971; called by muse, mutect2, varscan2
- ATAD2 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 146/369 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54885754; called by muse, mutect2, varscan2
- ATAD3A | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 100/411 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs765594985; called by muse, mutect2, varscan2
- ATAD3B | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 196/515 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.65); catalogued as rs761212122, COSV100426386; called by muse, varscan2
- ATAD5 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 138/305 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs770341123, COSV58976078; called by muse, mutect2, varscan2
- ATF3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 380/765 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs1389773222; called by muse, mutect2, varscan2
- ATF4 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 312/690 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs777862308; called by muse, mutect2, varscan2
- ATG101 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 247/585 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs773286579; called by muse, mutect2, varscan2
- ATG14 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as COSV55957097; called by muse, mutect2, varscan2
- ATG16L1 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 125/300 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs1362051933; called by muse, mutect2, varscan2
- ATG16L1 | c.1751C>T p.A584V (on ENST00000392017 / NM_030803.7; = p.A565V on NM_017974.4) | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs756788551, COSV61467337; called by muse, varscan2
- ATL2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 168/390 reads (43%) | catalogued as COSV60050674; called by muse, varscan2
- ATMIN | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 142/346 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs146769334; called by muse, mutect2, varscan2
- ATN1 | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 294/570 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1403061751, COSV57547247; called by muse, mutect2, varscan2
- ATP11A | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 174/381 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs766679862; called by muse, mutect2, varscan2
- ATP11C | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 187/380 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59560697, COSV59561511; called by muse, mutect2, varscan2
- ATP13A2 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 122/312 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771707117, COSV58702165; called by muse, varscan2
- ATP13A2 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 122/282 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs1213129765; called by muse, mutect2, varscan2
- ATP1A4 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 193/428 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.044); catalogued as rs1408920397; called by muse, mutect2, varscan2
- ATP1A4 | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 356/380 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233291589, COSV63627395; called by muse, mutect2, varscan2
- ATP1B2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 192/444 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs765060572, COSV51516875; called by muse, mutect2, varscan2
- ATP2A1 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 194/481 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs1286264854, COSV100450919; called by muse, mutect2, varscan2
- ATP2A3 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 190/458 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs781761104; called by muse, mutect2
- ATP2A3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs138857372; called by muse, mutect2, varscan2
- ATP2B3 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs373144811, COSV54848526; called by muse, mutect2
- ATP4A | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 164/304 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs145767701, COSV52866100; called by muse, mutect2, varscan2
- ATP4A | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 145/347 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs760994831; called by muse, mutect2, varscan2
- ATP4A | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 152/330 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs375031967; called by muse, mutect2, varscan2
- ATP5F1A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); catalogued as rs776215108, COSV56359787; called by muse, varscan2
- ATP5MGL | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs752249798; called by muse, mutect2, varscan2
- ATP6V0B | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 237/557 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs201522408, COSV52544080; called by muse, mutect2, varscan2
- ATP6V0B | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 242/538 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.182); catalogued as rs1261694939; called by muse, mutect2, varscan2
- ATP6V0D1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 268/561 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs34389524; called by muse, mutect2, varscan2
- ATP7B | c.4190C>T p.A1397V | Missense Mutation (SNP) | VAF 192/469 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1566430822; called by muse, varscan2
- ATP8B2 | c.536C>T p.A179V (on ENST00000672630; = p.A146V on NM_001005855.2) | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs776939812, COSV59245184; called by muse, varscan2
- ATP9A | c.2603C>T p.S868F | Missense Mutation (SNP) | VAF 170/395 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58771188; called by muse, varscan2
- ATP9B | c.3353C>T p.A1118V | Missense Mutation (SNP) | VAF 114/238 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1315208071, COSV56946103; called by muse, mutect2, varscan2
- ATR | c.7763C>T p.A2588V | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193847387; called by muse, mutect2
- ATRIP | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs756758036; called by muse, mutect2, varscan2
- ATRX | c.4557+1G>A p.X1519_splice | Splice Site (SNP) | VAF 80/160 reads (50%) | catalogued as COSV64876252; called by muse, mutect2, varscan2
- ATRX | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 273/702 reads (39%) | catalogued as rs1057523785, COSV64871339; called by muse, mutect2, varscan2
- ATXN2L | c.2866G>A p.G956S | Missense Mutation (SNP) | VAF 188/383 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs772084546; called by muse, mutect2, varscan2
- ATXN2L | c.3208C>T p.R1070W | Missense Mutation (SNP) | VAF 67/476 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs748027494; called by muse, mutect2, varscan2
- ATXN3L | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 323/630 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as rs369915965, COSV66075430; called by muse, mutect2, varscan2
- AUP1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 411/959 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51208126; called by muse, mutect2, varscan2
- AUP1 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 32/618 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1273285344, COSV51206994; called by muse, mutect2
- AURKC | c.106C>T p.R36W (on ENST00000302804 / NM_001015878.2; = p.R2W on NM_003160.3) | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs866773092; called by muse, varscan2
- AURKC | c.901C>A p.L301M (on ENST00000302804 / NM_001015878.2; = p.L267M on NM_003160.3) | Missense Mutation (SNP) | VAF 175/341 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs377167746; called by muse, mutect2, varscan2
- AUTS2 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 270/601 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1359937867, COSV61429769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AVIL | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 214/457 reads (47%) | catalogued as rs780595972; called by muse, mutect2, varscan2
- AVPR2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 99/169 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1557100783, COSV61685742; called by muse, mutect2, varscan2
- AXIN1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138744096; called by muse, mutect2, varscan2
- AXIN2 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 222/488 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs876660965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GAT1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 124/248 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1374536721; called by muse, mutect2, varscan2
- B3GNT6 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 217/447 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100845783; called by muse, mutect2, varscan2
- B3GNT6 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 137/298 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1555027789; called by muse, mutect2, varscan2
- B3GNT7 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 257/593 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406163511; called by muse, mutect2, varscan2
- B3GNT8 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs762570128, COSV54197707; called by muse, mutect2, varscan2
- B3GNTL1 | c.276C>T p.G92= | Splice Region (SNP) | VAF 63/146 reads (43%) | catalogued as rs143030444; called by muse, mutect2, varscan2
- B4GALNT4 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 152/336 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs761780147, COSV57323949; called by muse, varscan2
- B4GALT7 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 189/388 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs374994284; called by muse, mutect2, varscan2
- BABAM1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.285); catalogued as rs758868685, COSV53103833; called by muse, mutect2, varscan2
- BACE1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 150/366 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs552807233, COSV100326901; called by muse, mutect2, varscan2
- BACE1 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 228/574 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs770251178, COSV57286496; called by muse, mutect2, varscan2
- BAHCC1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 170/391 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs782698027, COSV57028325; called by muse, mutect2, varscan2
- BAHD1 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 162/396 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.2); catalogued as rs780974137, COSV69083917; called by muse, mutect2, varscan2
- BAIAP2L1 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 33/358 reads (9%) | catalogued as rs1385972037; called by muse, mutect2
- BAIAP2L1 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 165/357 reads (46%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.902); catalogued as rs1390139204, COSV99134246; called by muse, mutect2, varscan2
- BAP1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 228/526 reads (43%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1365625070, COSV56239497; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1554575752, COSV59989118; called by muse, mutect2, varscan2
- BBS12 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 333/713 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200240034, COSV58561755; called by muse, mutect2, varscan2
- BBS2 | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 57/704 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs976614614, COSV99802242; called by muse, mutect2
- BCAS4 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 199/446 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs759240930, COSV52815167; called by muse, mutect2, varscan2
- BCL11A | c.1991G>A p.R664H (on ENST00000335712 / NM_001365609.1; = p.R698H on NM_018014.4) | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs757462932, COSV59624142; called by muse, mutect2
- BCL11A | c.463G>A p.A155T (on ENST00000335712 / NM_001365609.1; = p.A189T on NM_018014.4) | Missense Mutation (SNP) | VAF 290/594 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59625213; called by muse, mutect2, varscan2
- BCL2L2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 264/533 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs764512287, COSV51635822; called by muse, mutect2, varscan2
- BCL6 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs369842677, COSV51652397; called by muse, mutect2, varscan2
- BCL7C | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 151/377 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs753453424; called by muse, mutect2, varscan2
- BCL9 | c.3035G>A p.R1012Q | Missense Mutation (SNP) | VAF 305/638 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs1553205574, COSV52342041, COSV52347420; called by muse, mutect2, varscan2
- BCLAF1 | c.1679A>G p.N560S | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.822); catalogued as COSV100786818; called by muse, mutect2, varscan2
- BCLAF1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 242/753 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs761434446, COSV62143043, COSV62144533; called by muse, mutect2, varscan2
- BCOR | c.3625C>T p.R1209C (on ENST00000378444 / NM_001123385.2; = p.R1175C on NM_017745.6) | Missense Mutation (SNP) | VAF 52/738 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60703819; called by muse, mutect2
- BCORL1 | c.4063C>T p.R1355W | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1316352614; called by muse, mutect2, varscan2
- BDH1 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 37/616 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs201898088; called by muse, mutect2
- BDKRB1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757505732, COSV99387865; called by muse, varscan2
- BDKRB1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs573449408, COSV53706364; called by muse, varscan2
- BEGAIN | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as rs943516054; called by muse, mutect2, varscan2
- BEND3 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1316134137, COSV64681621; called by muse, mutect2
- BFSP1 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs868488668; called by muse, mutect2, varscan2
- BGN | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 49/556 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV59036890; called by muse, mutect2
- BICRA | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs775636237; called by muse, mutect2, varscan2
- BIN2 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs150210505, COSV57205346; called by muse, mutect2, varscan2
- BIN3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 184/404 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as rs749714828, COSV52383955; called by muse, mutect2, varscan2
- BIRC2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 165/359 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as rs191312831, COSV57162287; called by muse, mutect2, varscan2
- BLCAP | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 237/468 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99289914; called by muse, mutect2, varscan2
- BMP1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs375180557; called by muse, mutect2
- BMP1 | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 202/469 reads (43%) | catalogued as rs773343328; called by muse, varscan2
- BMPR1A | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 222/515 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as rs779371501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs368430622; called by muse, mutect2, varscan2
- BNIP5 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 176/442 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.059); catalogued as rs779023756; called by muse, mutect2
- BOC | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 164/673 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs565408329, COSV56352611; called by muse, mutect2, varscan2
- BOD1L1 | c.2600G>T p.R867I | Missense Mutation (SNP) | VAF 99/792 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99239500; called by muse, mutect2, varscan2
- BPIFA2 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 186/472 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.095); catalogued as rs539973676; called by muse, mutect2, varscan2
- BPIFB2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 250/526 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs767736667, COSV50072276; called by muse, varscan2
- BPNT2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 199/498 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs758965196, COSV52907247; called by muse, mutect2, varscan2
- BPTF | c.7403G>A p.R2468H | Missense Mutation (SNP) | VAF 198/479 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.374); catalogued as rs910602094, COSV100076081; called by muse, mutect2, varscan2
- BRAT1 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs985353290; called by muse, mutect2, varscan2
- BRCA2 | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 146/386 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs276174893, COSV66456955; called by mutect2, varscan2
- BRD4 | c.3775C>T p.R1259C | Missense Mutation (SNP) | VAF 146/328 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1187497598, COSV99650130; called by muse, varscan2
- BRD4 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 195/423 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs747608142; called by muse, mutect2, varscan2
- BRINP2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 279/680 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771272662, COSV100838021, COSV64180814; called by muse, mutect2, varscan2
- BRINP2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 283/693 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as rs146557924; called by muse, mutect2, varscan2
- BROX | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 179/430 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372955065; called by muse, mutect2, varscan2
- BSN | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 292/593 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs757466787, COSV56515563; called by muse, mutect2, varscan2
- BTBD16 | c.474C>T p.V158= | Splice Region (SNP) | VAF 193/456 reads (42%) | catalogued as rs367755013; called by muse, mutect2, varscan2
- BTBD17 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 182/398 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs565716636, COSV64729988; called by muse, mutect2, varscan2
- BTBD3 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 335/718 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs754515054, COSV54778355; called by muse, mutect2, varscan2
- BTBD3 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 373/841 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1568617554; called by muse, mutect2, varscan2
- BTBD6 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs61740092, COSV100527472; called by muse, mutect2, varscan2
- BTBD7 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 155/323 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs866089872, COSV58283031; called by muse, varscan2
- BTBD7 | c.1586A>G p.N529S | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100598048; called by muse, mutect2
- BTN3A1 | c.1019-8C>T | Splice Region (SNP) | VAF 24/702 reads (3%) | catalogued as COSV99176152; called by muse, mutect2
- BTRC | c.1619G>A p.R540H (on ENST00000370187 / NM_033637.4; = p.R504H on NM_003939.5) | Missense Mutation (SNP) | VAF 49/501 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs760843942, COSV64579065; called by muse, mutect2, varscan2
- BUB1B | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 58/648 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.158); catalogued as rs1347040377; called by muse, mutect2
- BUB3 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 275/624 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64363654, COSV64363756; called by muse, mutect2, varscan2
- BX276092.9 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 118/220 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs748292134; called by muse, mutect2, varscan2
- BYSL | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 185/418 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs765781821, COSV57828419; called by muse, mutect2, varscan2
- BZW1 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs764713691; called by muse, mutect2, varscan2
- C10orf71 | c.1943G>T p.R648M | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99055237; called by muse, mutect2, varscan2
- C10orf90 | c.1869G>T p.K623N | Missense Mutation (SNP) | VAF 220/464 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99503582; called by muse, varscan2
- C11orf16 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 204/480 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297876107; called by muse, mutect2, varscan2
- C11orf52 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 160/403 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs144473843; called by muse, mutect2, varscan2
- C11orf86 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 174/410 reads (42%) | catalogued as rs890216098; called by muse, varscan2
- C15orf39 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 179/406 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1317526889, COSV62296754, COSV62298266; called by muse, mutect2, varscan2
- C17orf107 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 232/555 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.668); catalogued as rs1039173948, COSV53417149; called by muse, mutect2, varscan2
- C17orf113 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 90/184 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs886986088, COSV71536894; called by muse, mutect2, varscan2
- C17orf64 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 216/451 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.041); catalogued as rs747093678, COSV52255902; called by muse, mutect2, varscan2
- C17orf97 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782721931; called by muse, mutect2
- C17orf99 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 141/315 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as rs747257997; called by muse, mutect2, varscan2
- C1QTNF6 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 199/427 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs1462176247, COSV55396945; called by muse, mutect2, varscan2
- C1orf127 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 149/338 reads (44%) | catalogued as rs1191090823; called by muse, mutect2, varscan2
- C1orf54 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV64257149; called by muse, mutect2, varscan2
- C1orf74 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 190/422 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV50553396; called by muse, mutect2, varscan2
- C22orf15 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs200704446, COSV100533515; called by muse, mutect2, varscan2
- C2CD3 | c.6785C>T p.T2262M | Missense Mutation (SNP) | VAF 166/384 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1387969007; called by muse, mutect2, varscan2
- C2CD6 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV53799937; called by muse, mutect2
- C2orf92 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 223/470 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1048541852, COSV101491199; called by muse, mutect2, varscan2
- C3 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55579741; called by muse, mutect2, varscan2
- C3 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs778521833; called by muse, mutect2, varscan2
- C3orf33 | c.859C>T p.R287C (on ENST00000340171 / NM_001308229.2; = p.R244C on NM_173657.2) | Missense Mutation (SNP) | VAF 115/261 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1414381648; called by muse, mutect2, varscan2
- C4B | c.4055G>A p.R1352H | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1199649021; called by mutect2, varscan2
- C4BPB | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1004689013, COSV54691491; called by muse, mutect2
- C4orf50 | c.572C>T p.S191F (on ENST00000324058; = p.S1423F on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1560568445, COSV100136097; called by muse, mutect2, varscan2
- C5 | c.3677G>A p.R1226H | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs756426099, COSV99797797; called by muse, mutect2
- C5 | c.3277G>A p.V1093I | Missense Mutation (SNP) | VAF 172/401 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs371131390; called by muse, mutect2, varscan2
- C5orf24 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 181/385 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.01); catalogued as COSV57543101; called by muse, mutect2, varscan2
- C5orf47 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.08); catalogued as rs1481467890, COSV60864278; called by muse, mutect2, varscan2
- C7orf33 | c.459C>T p.N153= | Splice Region (SNP) | VAF 150/276 reads (54%) | catalogued as rs768863009; called by muse, mutect2, varscan2
- C8orf48 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 233/497 reads (47%) | catalogued as rs766448217; called by muse, mutect2, varscan2
- C9orf131 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202238614; called by muse, mutect2, varscan2
- C9orf78 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774971405; called by muse, mutect2, varscan2
- CACFD1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 187/452 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782149054; called by muse, mutect2, varscan2
- CACHD1 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 194/434 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs991230647, COSV51560225; called by muse, mutect2, varscan2
- CACNA1A | c.6481C>T p.R2161C | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs766661019; called by muse, varscan2
- CACNA1B | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 204/499 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1258883145; called by muse, mutect2, varscan2
- CACNA1B | c.3481G>A p.A1161T | Missense Mutation (SNP) | VAF 63/553 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as rs200326973; called by muse, mutect2, varscan2
- CACNA1D | c.3535G>A p.A1179T (on ENST00000350061 / NM_001128840.3; = p.A1199T on NM_000720.4) | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs757830356, COSV55448464; called by muse, mutect2, varscan2
- CACNA1D | c.5377C>T p.R1793W (on ENST00000350061 / NM_001128840.3; = p.R1813W on NM_000720.4) | Missense Mutation (SNP) | VAF 263/519 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.072); catalogued as rs555675934; called by muse, mutect2, varscan2
- CACNA1E | c.4465G>A p.A1489T | Missense Mutation (SNP) | VAF 258/654 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs1188254439, COSV62393791; called by muse, mutect2, varscan2
- CACNA1F | c.5882G>A p.R1961H | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as rs782337448, COSV54294494; called by muse, mutect2, varscan2
- CACNA1F | c.4427G>A p.R1476H | Missense Mutation (SNP) | VAF 206/367 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs868968074; called by muse, mutect2, varscan2
- CACNA1F | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59903562; called by muse, mutect2
- CACNA1F | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 173/456 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs781975294; called by muse, mutect2, varscan2
- CACNA1H | c.3934G>A p.A1312T | Missense Mutation (SNP) | VAF 72/664 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1056947025, COSV61983214; called by muse, mutect2, varscan2
- CACNA2D1 | c.2538+1G>A p.X846_splice (on ENST00000356253 / NM_001366867.1; = p.X834_splice on NM_000722.4) | Splice Site (SNP) | VAF 236/559 reads (42%) | catalogued as rs1271475686, COSV62391967; called by muse, mutect2, varscan2
- CACNG5 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 287/571 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs375809079, COSV50058275; called by muse, mutect2, varscan2
- CACNG8 | c.106A>C p.T36P | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV54414162; called by muse, mutect2, varscan2
- CADM1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 203/509 reads (40%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.683); catalogued as rs986045773, COSV59017228; called by muse, mutect2, varscan2
- CADM2 | c.701C>T p.S234L (on ENST00000407528 / NM_001167674.2; = p.S236L on NM_153184.4) | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1002347395; called by muse, mutect2
- CADM3 | c.962C>T p.P321L (on ENST00000368125 / NM_001127173.3; = p.P355L on NM_021189.5) | Missense Mutation (SNP) | VAF 132/267 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as rs777264746, COSV63676683; called by muse, mutect2, varscan2
- CADPS | c.3734G>A p.R1245H | Missense Mutation (SNP) | VAF 340/718 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1190512729; called by muse, mutect2, varscan2
- CALCOCO1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 140/329 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759818625; called by muse, mutect2, varscan2
- CALCOCO1 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 153/344 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs1478603135; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 112/336 reads (33%) | catalogued as rs1486659949; called by mutect2, varscan2
- CALHM2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 252/536 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs756784159, COSV53298020; called by muse, mutect2, varscan2
- CALHM3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 177/363 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1236415544, COSV100873349; called by muse, mutect2, varscan2
- CALHM5 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 46/868 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV62067838; called by muse, mutect2
- CAMK1 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV56539340; called by muse, mutect2, varscan2
- CAMK2B | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.444); catalogued as rs1163572646, COSV51664606; called by muse, mutect2, varscan2
- CAMKK2 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as rs201742753; called by muse, mutect2, varscan2
- CAMSAP2 | c.3715C>T p.R1239W (on ENST00000236925 / NM_001297707.2; = p.R1228W on NM_203459.3) | Missense Mutation (SNP) | VAF 205/473 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199622691, COSV52667532; called by muse, mutect2, varscan2
- CAMSAP3 | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs771683691, COSV50333545; called by muse, mutect2, varscan2
- CAMTA2 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 216/493 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373579185; called by muse, mutect2, varscan2
- CAMTA2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs756160547; called by muse, mutect2
- CAP2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 118/244 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs755478362; called by muse, mutect2, varscan2
- CAPN10 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 155/348 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as rs764148287, COSV54378260; called by muse, mutect2, varscan2
- CAPN11 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV67238535; called by muse, mutect2
- CAPN13 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 170/370 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs565060477, COSV54429720; called by muse, varscan2
- CAPN15 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 150/355 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs752712228; called by muse, mutect2, varscan2
- CAPN5 | c.499C>T p.R167C (on ENST00000456580; = p.R127C on NM_004055.5) | Missense Mutation (SNP) | VAF 183/401 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as rs559189456, COSV53687927; called by muse, mutect2, varscan2
- CAPN5 | c.1499G>A p.R500H (on ENST00000456580; = p.R460H on NM_004055.5) | Missense Mutation (SNP) | VAF 214/484 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs373394985, COSV53689020; called by muse, varscan2
- CARD11 | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as rs895214237, COSV62754327; called by muse, mutect2
- CARMIL1 | c.4052G>A p.G1351D | Missense Mutation (SNP) | VAF 233/519 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as rs375252687; called by muse, mutect2, varscan2
- CARMIL2 | c.3794G>A p.R1265H | Missense Mutation (SNP) | VAF 222/550 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1038290739; called by muse, mutect2, varscan2
- CARMIL3 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 158/354 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as rs755372542; called by muse, varscan2
- CARNS1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 139/239 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as rs775422380, COSV100321794; called by muse, varscan2
- CARS1 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 38/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461372759, COSV53453285; called by muse, mutect2
- CASKIN1 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as rs1311839596; called by muse, mutect2, varscan2
- CASKIN1 | c.3092G>A p.R1031H | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs561530080; called by muse, mutect2, varscan2
- CASKIN1 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 174/388 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1006428427; called by muse, varscan2
- CASKIN1 | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 172/351 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs768552379; called by muse, varscan2
- CASKIN1 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 158/377 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374770264; called by muse, mutect2, varscan2
- CASKIN2 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 155/310 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs555821727, COSV58596144; called by muse, mutect2, varscan2
- CASKIN2 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 156/378 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs978077636; called by muse, varscan2
- CASP2 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as rs766876353, COSV60082254; called by muse, mutect2, varscan2
- CASZ1 | c.973C>A p.L325M | Missense Mutation (SNP) | VAF 177/417 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as COSV59739534; called by mutect2, varscan2
- CATSPER1 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 189/413 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as rs773724360; called by muse, mutect2, varscan2
- CAVIN2 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 268/591 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1169130523; called by muse, mutect2, varscan2
- CBFA2T2 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 176/431 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.204); catalogued as rs57375754, COSV60800443; called by muse, mutect2, varscan2
- CBL | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99876488; called by muse, mutect2, varscan2
- CBLB | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 253/586 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); catalogued as rs757777424; called by muse, varscan2
- CBLB | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 277/660 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV51426934; called by muse, varscan2
- CBLL1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 225/477 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.431); catalogued as rs267601227; called by muse, mutect2, varscan2
- CBX8 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 147/344 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV53937813; called by muse, mutect2, varscan2
- CCDC115 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 100/693 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs765974155, COSV52091171; called by muse, mutect2, varscan2
- CCDC120 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 172/359 reads (48%) | catalogued as rs1263418293, COSV100900721; called by muse, mutect2, varscan2
- CCDC127 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 191/356 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57257588; called by muse, mutect2, varscan2
- CCDC127 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 335/696 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs751645944; called by muse, mutect2, varscan2
- CCDC14 | c.1105C>T p.R369* (on ENST00000488653; = p.R321* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 327/698 reads (47%) | catalogued as rs200601158, COSV59943859; called by muse, mutect2, varscan2
- CCDC141 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 193/429 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV55373209; called by muse, mutect2, varscan2
- CCDC149 | c.1273G>A p.A425T (on ENST00000635206 / NM_001330643.2; = p.A414T on NM_173463.5) | Missense Mutation (SNP) | VAF 32/742 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.018); catalogued as rs866274450; called by muse, mutect2
- CCDC149 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 215/497 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs371812850; called by muse, mutect2, varscan2
- CCDC150 | c.807A>G p.I269M | Missense Mutation (SNP) | VAF 240/531 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs759255228; called by muse, mutect2, varscan2
- CCDC168 | c.17512C>T p.R5838* | Nonsense Mutation (SNP) | VAF 175/417 reads (42%) | catalogued as rs371478604; called by muse, mutect2, varscan2
- CCDC168 | c.17024C>T p.P5675L | Missense Mutation (SNP) | VAF 250/531 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371366499; called by muse, mutect2, varscan2
- CCDC175 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 155/339 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as rs981806129; called by muse, mutect2, varscan2
- CCDC177 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 143/340 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as rs954007038; called by muse, mutect2, varscan2
- CCDC183 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 204/490 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs759534715; called by muse, mutect2, varscan2
- CCDC22 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 156/398 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372144369, COSV66052201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC30 | c.1436C>T p.S479F (on ENST00000340612; = p.S436F on NM_001080850.3) | Missense Mutation (SNP) | VAF 161/459 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV59609206, COSV59609619; called by muse, mutect2, varscan2
- CCDC39 | c.1917G>T p.K639N | Missense Mutation (SNP) | VAF 241/538 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99867048; called by muse, mutect2, varscan2
- CCDC60 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 161/353 reads (46%) | catalogued as rs1391114829; called by muse, mutect2, varscan2
- CCDC73 | c.1825G>T p.G609W | Missense Mutation (SNP) | VAF 29/506 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100068400; called by muse, mutect2
- CCDC85C | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as rs1378883041; called by muse, mutect2, varscan2
- CCDC88B | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 99/208 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.354); catalogued as rs375634325; called by muse, mutect2, varscan2
- CCDC88C | c.4496G>A p.R1499H | Missense Mutation (SNP) | VAF 279/573 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs752609625; called by muse, mutect2, varscan2
- CCDC9 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs753790394, COSV99699777; called by muse, mutect2
- CCHCR1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 212/474 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs777814086; called by muse, mutect2, varscan2
- CCL3L3 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 34/706 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1249997768; called by muse, mutect2
- CCNC | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 186/440 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314175799; called by muse, varscan2
- CCNL2 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 123/318 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs769240244; called by muse, mutect2, varscan2
- CCNP | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 148/344 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs779420643; called by muse, mutect2, varscan2
- CCP110 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 189/449 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as rs746844150, COSV66817352; called by muse, mutect2, varscan2
- CCR9 | c.916G>A p.A306T (on ENST00000357632 / NM_031200.3; = p.A294T on NM_006641.4) | Missense Mutation (SNP) | VAF 320/739 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1346189977; called by muse, mutect2, varscan2
- CCS | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 147/348 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302260691; called by muse, mutect2, varscan2
- CCT5 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 189/427 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs765772467, COSV54724248; called by muse, mutect2, varscan2
- CCT8L2 | c.633dup p.T212Dfs*52 | Frame Shift Ins (INS) | VAF 122/236 reads (52%) | catalogued as rs767593972; called by mutect2, varscan2
- CD163L1 | c.3940C>T p.R1314W | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs372730324, COSV58026616; called by muse, mutect2, varscan2
- CD164 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 196/452 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51532853; called by muse, mutect2, varscan2
- CD1C | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 23/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs989408136, COSV63807634; called by muse, mutect2
- CD22 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.592); catalogued as rs551837423; called by muse, mutect2, varscan2
- CD276 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 165/366 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs747735855; called by muse, mutect2, varscan2
- CD2BP2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 241/561 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1456411631; called by muse, mutect2, varscan2
- CD300LB | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1011648660; called by muse, mutect2, varscan2
- CD4 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 142/304 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs782149774; called by muse, mutect2, varscan2
- CD63 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 155/349 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as rs756637406, COSV57677489; called by muse, mutect2, varscan2
- CD83 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 155/330 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs147342996, COSV64788109; called by muse, mutect2, varscan2
- CD9 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as rs929350862, COSV99152794; called by muse, mutect2, varscan2
- CDC14B | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 240/499 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs151098648; called by muse, mutect2, varscan2
- CDC27 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745491637, COSV50374936; called by muse, mutect2, varscan2
- CDC42BPB | c.4250C>T p.A1417V | Missense Mutation (SNP) | VAF 110/237 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as rs776462657, COSV63475910; called by muse, mutect2, varscan2
- CDC42BPG | c.4297C>T p.R1433C | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397682003, COSV61347429; called by muse, mutect2, varscan2
- CDC42BPG | c.3727G>A p.A1243T | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs764061134; called by muse, mutect2
- CDC42BPG | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 325/712 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs753090372, COSV104418042; called by muse, mutect2, varscan2
- CDC73 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100813823; called by muse, mutect2, varscan2
- CDCA2 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 129/311 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100398815; called by muse, mutect2, varscan2
- CDCA3 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 149/345 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs1322261982, COSV57528803; called by muse, mutect2, varscan2
- CDCA7L | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 222/557 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs777536863; called by muse, mutect2, varscan2
- CDH12 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 249/584 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66413472; called by muse, mutect2, varscan2
- CDH22 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 201/437 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768598036, COSV100952986; called by muse, mutect2, varscan2
- CDH23 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 151/363 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs777365157, COSV99819694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK11B | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs774860795; called by muse, mutect2, varscan2
- CDK20 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 245/540 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs754792892; called by muse, mutect2
- CDK5RAP3 | c.988+1G>A p.X330_splice | Splice Site (SNP) | VAF 156/348 reads (45%) | catalogued as rs757902318; called by muse, mutect2, varscan2
- CDKL1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53583538; called by muse, mutect2, varscan2
- CDKL2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56732175; called by muse, mutect2, varscan2
- CDKN2D | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 162/364 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868167883; called by muse, mutect2, varscan2
- CDRT1 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 232/528 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372307584; called by muse, mutect2
- CDRT15L2 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); catalogued as rs1264790586; called by muse, mutect2, varscan2
- CDT1 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 267/629 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs146872515, COSV56348396; called by muse, mutect2, varscan2
- CDT1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 194/430 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1234385024; called by muse, varscan2
- CDT1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 194/596 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs143840572; ClinVar: not provided; called by muse, varscan2
- CEACAM18 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.88); catalogued as COSV67284443; called by muse, mutect2, varscan2
- CEACAM21 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as COSV99494786; called by mutect2, varscan2
- CEBPB | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 69/543 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57276966; called by muse, mutect2, varscan2
- CECR2 | c.805C>T p.R269W (on ENST00000342247 / NM_001290047.2; = p.R106W on NM_001290046.1) | Missense Mutation (SNP) | VAF 29/476 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1569127896; called by muse, mutect2
- CEL | c.391G>A p.A131T (on ENST00000673714; = p.A128T on NM_001807.6) | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1269812562; called by muse, mutect2, varscan2
- CELA2B | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs773571189; called by muse, mutect2, varscan2
- CELA3A | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 104/576 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755408644; called by muse, mutect2
- CELA3B | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs534541989; called by muse, mutect2, varscan2
- CELF1 | c.1411C>T p.R471W (on ENST00000358597 / NM_001376422.1; = p.R467W on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 343/736 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV60113818; called by muse, mutect2, varscan2
- CELSR1 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs1331058696; called by muse, mutect2, varscan2
- CELSR1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 236/518 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as rs1315057852, COSV99417190; called by muse, mutect2, varscan2
- CELSR2 | c.3725G>A p.R1242H | Missense Mutation (SNP) | VAF 196/437 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs147011024, COSV104375626; called by muse, mutect2, varscan2
- CELSR2 | c.7978G>A p.G2660R | Missense Mutation (SNP) | VAF 215/463 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774661882, COSV99604448; called by muse, mutect2, varscan2
- CELSR3 | c.9482G>A p.R3161H | Missense Mutation (SNP) | VAF 201/466 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.083); catalogued as rs772862640; called by muse, mutect2, varscan2
- CELSR3 | c.8297C>T p.A2766V | Missense Mutation (SNP) | VAF 190/389 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs755164071; called by muse, mutect2, varscan2
- CELSR3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 166/364 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV50840456; called by muse, mutect2, varscan2
- CEMIP | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 137/334 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs375136109; called by muse, mutect2, varscan2
- CEMIP | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 240/514 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); catalogued as rs759087523; called by muse, mutect2, varscan2
- CEMIP | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 318/666 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767253792, COSV54995823; called by muse, mutect2, varscan2
- CENPM | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 216/460 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs773182401; called by muse, mutect2, varscan2
- CEP112 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 54/734 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs758742223, COSV67140061; called by muse, mutect2
- CEP120 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 243/579 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs375645626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP135 | c.2938C>T p.L980F | Missense Mutation (SNP) | VAF 87/684 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57261165; called by muse, mutect2, varscan2
- CEP162 | c.4171C>T p.P1391S | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1451159190, COSV57624272; called by muse, mutect2
- CEP162 | c.3847C>T p.R1283* | Nonsense Mutation (SNP) | VAF 305/673 reads (45%) | catalogued as rs1191200730, COSV100002406; called by muse, mutect2, varscan2
- CEP162 | c.1007dup p.N336Kfs*8 | Frame Shift Ins (INS) | VAF 143/316 reads (45%) | catalogued as rs1246596907; called by mutect2, varscan2
- CEP164 | c.4376G>A p.R1459H | Missense Mutation (SNP) | VAF 219/545 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99634494; called by muse, mutect2, varscan2
- CEP170B | c.3535G>A p.G1179S (on ENST00000453495; = p.G1108S on NM_015005.3) | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as rs578240281; called by muse, mutect2, varscan2
- CEP192 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100382467; called by muse, varscan2
- CEP192 | c.3122C>T p.T1041M | Missense Mutation (SNP) | VAF 155/356 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs563824737; called by muse, mutect2, varscan2
- CEP250 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 153/357 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs780173303, COSV61168683; called by muse, mutect2, varscan2
- CEP250 | c.6946C>T p.R2316C | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs546441918, COSV61171411; called by muse, mutect2, varscan2
- CEP295 | c.1657dup p.T553Nfs*18 | Frame Shift Ins (INS) | VAF 103/260 reads (40%) | catalogued as rs749718914; called by mutect2, varscan2
- CEP350 | c.5230C>T p.R1744C | Missense Mutation (SNP) | VAF 177/406 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1416558863; called by muse, mutect2, varscan2
- CEP350 | c.7408C>T p.R2470C | Missense Mutation (SNP) | VAF 165/413 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs778785732, COSV62604980; called by muse, mutect2, varscan2
- CEP78 | c.1229G>A p.R410H (on ENST00000424347 / NM_001349840.2; = p.R411H on NM_032171.3) | Missense Mutation (SNP) | VAF 179/397 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757117060; called by muse, mutect2, varscan2
- CEP83 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 139/311 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767118598, COSV60409300; called by muse, mutect2, varscan2
- CEP85L | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 226/599 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1166947586; called by muse, mutect2, varscan2
- CERCAM | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 246/515 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1322757381; called by muse, mutect2, varscan2
- CERS1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs780713994, COSV55930322; called by muse, mutect2, varscan2
- CERS2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 248/521 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1355471060; called by muse, mutect2, varscan2
- CERS6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 187/443 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs755919514, COSV59834601; called by muse, mutect2, varscan2
- CETP | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 217/525 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs1326253991, COSV52361747; called by muse, mutect2, varscan2
- CFAP100 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 199/378 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1560071362; called by muse, mutect2, varscan2
- CFAP157 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 136/371 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as rs749457482; called by muse, mutect2, varscan2
- CFAP251 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 233/438 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as rs747181909; called by muse, mutect2, varscan2
- CFAP46 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 262/561 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as COSV63949649; called by muse, mutect2, varscan2
- CFAP58 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 62/557 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs61732088; called by muse, mutect2, varscan2
- CFAP65 | c.5327A>G p.E1776G | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV58561944; called by muse, mutect2
- CFAP65 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 244/546 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748008475; called by muse, mutect2, varscan2
- CFAP77 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs765507051, COSV58011972; called by muse, mutect2, varscan2
- CGB1 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415924632, COSV100031427; called by muse, mutect2, varscan2
- CGB2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 156/697 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1196406402; called by muse, varscan2
- CGB5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1201663825; called by mutect2, varscan2
- CGB7 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 164/698 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1340391201; called by muse, varscan2
- CGN | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 143/318 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.072); catalogued as rs1335984124; called by muse, mutect2, varscan2
- CHAD | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 61/494 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as rs747986628, COSV51970808; called by muse, mutect2, varscan2
- CHAF1A | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1266443865; called by muse, mutect2
- CHAF1B | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 148/330 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757468123; called by muse, mutect2, varscan2
- CHD3 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 266/604 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57877155; called by muse, mutect2, varscan2
- CHD4 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 236/501 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs1270212341; called by muse, mutect2, varscan2
- CHD7 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 262/572 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs942764555; called by muse, varscan2
- CHD8 | c.5975G>A p.R1992H (on ENST00000646647 / NM_001170629.2; = p.R1713H on NM_020920.4) | Missense Mutation (SNP) | VAF 184/464 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs372488156, COSV63036670; called by muse, mutect2, varscan2
- CHD8 | c.4285C>T p.R1429W (on ENST00000646647 / NM_001170629.2; = p.R1150W on NM_020920.4) | Missense Mutation (SNP) | VAF 197/439 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs780639697; called by muse, mutect2, varscan2
- CHERP | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 130/349 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs543141111, COSV99550385; called by muse, mutect2, varscan2
- CHFR | c.1496G>A p.R499H (on ENST00000432561 / NM_001161345.1; = p.R458H on NM_018223.2) | Missense Mutation (SNP) | VAF 157/335 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs944300584, COSV57172071; called by muse, mutect2, varscan2
- CHL1 | c.3556G>A p.A1186T (on ENST00000397491 / NM_001253387.1; = p.A1202T on NM_006614.4) | Missense Mutation (SNP) | VAF 249/565 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs201186309, COSV104374520; called by muse, mutect2, varscan2
- CHML | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 62/705 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1558447999; called by muse, mutect2
- CHMP3 | c.45+8C>T | Splice Region (SNP) | VAF 138/297 reads (46%) | catalogued as rs1253150814; called by muse, mutect2, varscan2
- CHPT1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 188/402 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs910416069; called by muse, mutect2, varscan2
- CHRNA2 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 232/466 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as rs755631456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA2 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 226/471 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368791756, COSV53556413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 127/280 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.916); catalogued as rs201622476, COSV63808315; called by muse, mutect2, varscan2
- CHRNB3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs745572319, COSV51495825; called by muse, mutect2, varscan2
- CHRNB4 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 165/386 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs576926309; called by muse, mutect2, varscan2
- CHRND | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 177/417 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775578238, COSV99286189; called by muse, mutect2, varscan2
- CHRND | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 196/413 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1019213889; called by muse, mutect2, varscan2
- CHRNE | c.601+6G>T | Splice Region (SNP) | VAF 131/275 reads (48%) | catalogued as rs770104872; called by muse, mutect2, varscan2
- CHST12 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1249032971, COSV51676701; called by muse, mutect2
- CHST3 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 135/338 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378815381, COSV100910529; called by muse, mutect2, varscan2
- CHST3 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 42/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64151482; called by muse, mutect2
10,133 further variants in this file (5,843 protein-altering or splice-affecting, 2,542 silent, 1,748 other) are not listed here.
